Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A3EO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A3EO-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN #
Ref Ph,

PHYSICIAN INFORMATION

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right ovary and fallopian tube, excision:
No significant pathologic abnormality.
- B. Left ovary and fallopian tube, excision:
No significant pathologic abnormality.

C. Radical hysterectomy:

Tumor Characteristics:

1. Histologic type: Endocervical adenocarcinoma.
2. Histologic grade: Grade II, well differentiated.
3. Tumor site: Endocervix.
4. Tumor size: 3.3 x 3.0 x 1.5 cm.
5. Stromal invasion: Tumor extends through the cervical wall focally extending into the paracervical tissue on the left side.

Surgical Margin Status:

1. Inked paracervical margins negative for tumor, although tumor present within paracervical soft tissue.
Tumor extends to the vaginal cuff margin of resection.

Lymph Node Status:

1. One paracervical lymph node negative for malignancy present.
2. Additional lymph nodes: See parts E, F, G, H, I and J.

Other:

1. Other significant findings: Endometrial tissue without evidence of malignancy.
Myometrial tissue without evidence of malignancy.
Uterine serosa without evidence of malignancy.
2. pTNM stage: pT2b N0 (FIGO IIV).

D. Vagina, biopsy:

Vaginal wall tissue without evidence of malignancy.

E. Left external iliac lymph nodes, excision:

Three lymph nodes, negative for metastatic disease.

F. Left obturator lymph nodes, excision:

Six lymph nodes, negative for metastatic disease.

G. Left common lymph nodes, excision:

Two lymph nodes, negative for metastatic disease.

H. Right external iliac lymph nodes, excision:

Six lymph nodes, negative for metastatic disease.

I. Right obturator lymph nodes, excision:

Two lymph nodes, negative for metastatic disease.

J. Right common lymph nodes, excision:

Three lymph nodes, negative for metastatic disease.

K. Vagina, biopsy:

Adenocarcinoma present within deep wall.

Reviewed Initials	KMI	

ICD-0-3

adenocarcinoma, NOS (endocervical)
8140/3

Site: cervix, NOS C53.9 10/31/11

Electronic Signature: - - -

[page 2 of 2]
CLINICAL HISTORY:

Preoperative Diagnosis: Cervical cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right tube/ovary
- B. Left tube/ovary
- C. Radical hysterectomy
- D. Vagina
- E. Left external iliac lymph node
- F. Left obturator lymph node
- G. Left common lymph node
- H. Right external iliac lymph node
- I. Right obturator lymph nodes
- J. Right common lymph nodes
- K. Vaginal biopsy

SPECIMEN DATA:**GROSS DESCRIPTION:**

The specimen is received in eleven formalin-filled containers labeled with patient name

- A. Container A is additionally labeled right tube and ovary and contains a 2.8 gm, 3.0 x 1.5 x 1.0 cm, yellow-tan lobulated ovary received with attached parovarian soft tissue and segment of fimbriated fallopian tube. The tube has been previously interrupted. When reconstructed, it is 3.0 cm in length and ranges from 0.5 to 0.7 cm in diameter. The ovary is sectioned to reveal a yellow-tan, fibrous cut surface with multiple gray-white corpora albicantia. Representative sections are submitted in cassettes A1-3, labeled as follows: A1 – cross sections of fallopian tube; 2-3 – ovary.
- B. Container B is additionally labeled left tube and ovary and contains a 2.8 gm, 3.5 x 1.7 x 1.0 cm, yellow-tan, lobulated ovary received with attached parovarian soft tissue and segment of fimbriated fallopian tube. The tube has been previously interrupted and is 4.4 cm in length by 0.6 cm in diameter when reconstructed. The ovary is sectioned to reveal a yellow-gray, fibrous cut surface with multiple gray-white corpora albicantia. Representative sections are submitted in cassettes B1-3, labeled as follows: B1 – cross sections of fallopian tube; B2-3 – ovary.
- C. Container C is additionally labeled radical hysterectomy and contains a radical hysterectomy specimen devoid of adnexa. The specimen is comprised of a uterine corpus (4.0 cm in length by 2.8 x 2.0 cm), uterine cervix (3.5 cm in length by 2.3 x 2.0 cm), vaginal cuff (1.5 cm in length), right paracervical soft tissue (3.0 x 2.5 x 2.3 cm), and left paracervical soft tissue (3.5 x 2.8 x 1.5 cm). The paracervical soft tissues are inked. On sectioning and palpation, a possible 0.4 cm, firm, fatty lymph node is identified within the right paracervical soft tissues. The uterine serosa is pink-tan and glistening. The vaginal mucosa is pink-tan, wrinkled and glistening. The specimen is bivalved to reveal a 3.3 x 3.0 x 1.5 cm, pink-tan, fungating and friable mass involving the cervix and approaching to within 0.5 cm of the vaginal cuff margin. The remainder of the vaginal mucosa is pink-tan, wrinkled and glistening with no additional lesions. On sectioning, this mass extends 1.0 cm into a 1.1 cm thick, pink-tan, fibrous and focally cystic paracervix. The triangular endometrium is pink-tan, glistening, with an average thickness of 0.1 cm. The surrounding myometrium is pink-tan and fibrous with an average thickness of 1.1 cm. No myometrial nodules or lesions are identified. Representative sections are submitted in cassettes C1-15, labeled as follows: C1 – one whole possible right paracervical lymph node; C2 – vaginal cuff margin, en face; C3 – right paracervix, perpendicular; C4 – left paracervix, perpendicular; 5-7 – anterior cervix to include mass; C8-11 – posterior cervix to include mass at deepest extent of invasion; 12 – anterior lower uterine segment; 13 – posterior lower uterine segment; 14 – full thickness anterior endomyometrium; 15 – full thickness posterior endomyometrium. Additionally, a yellow, a green, and a blue cassette are submitted for genomics research, each labeled.
- D. Container D is additionally labeled vagina and contains a 1.0 x 0.7 cm, wedge of pink-tan, wrinkled and glistening soft tissue excised to a depth of 0.5 cm. The specimen is bisected and entirely submitted in cassette D, labeled.
- E. Container E is additionally labeled left external iliac lymph node and contains a 5.0 x 4.7 x 1.8 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, three firm, fatty possible lymph nodes are identified ranging from 1.0 up to 2.0 cm in greatest dimension. They are entirely submitted in cassettes E1-2, labeled as follows: E1 – two whole possible lymph nodes; E2 – one whole possible bisected lymph node.
- F. Container F is additionally labeled left obturator lymph node and contains a 5.0 x 3.5 x 3.5 cm aggregate of yellow-tan, fibrofatty soft tissue. On palpation, six possible firm, fatty lymph nodes are identified ranging from 0.4 up to 2.0 cm in greatest dimension. They are entirely submitted in cassettes F1-3, labeled as follows: F1 – one whole possible lymph node; F2 – two whole possible lymph nodes; F3 – three whole possible lymph nodes.
- G. Container G is additionally labeled left common lymph node and contains a 2.8 x 1.2 cm aggregate of yellow-tan, fibrofatty soft tissue. On palpation, two firm, fatty possible lymph nodes are identified, 0.4 and 0.5 cm in greatest dimension. They are entirely submitted in cassette G, labeled.
- H. Container H is additionally labeled right external iliac lymph node and contains a 5.5 x 4.8 x 2.8 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, six firm, fatty possible lymph nodes are identified ranging from 0.6 up to 2.5 cm in greatest dimension. They are entirely submitted in cassettes H1-4, labeled as follows: H1 – three whole possible lymph nodes; H2-4 – one whole possible bisected lymph node in each cassette.
- I. Container I is additionally labeled right obturator and contains a 4.3 x 3.3 x 1.8 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, two firm, fatty possible lymph nodes are identified, 0.9 and 2.0 cm in greatest dimension. They are entirely submitted in cassette I, labeled.
- J. Container J is additionally labeled right common lymph node and contains a 3.5 x 3.0 x 2.0 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, three firm, fatty possible lymph nodes are identified ranging from 0.5 up to 1.0 cm in greatest dimension. They are entirely submitted in cassette J, labeled.
- K. Container K is additionally labeled vaginal biopsy and contains three pink-tan, rubbery, irregular soft tissues ranging from 0.3 up to 0.8 cm in greatest dimension. The specimen is wrapped in tissue paper and entirely submitted in cassette K, labeled.

Source: NCI Genomic Data Commons file e4bfd06b-a74c-4dd5-b1e8-09f3eb8ef572 (TCGA-FU-A3EO.FA82B92B-202A-44B2-B186-F38F2C33E062.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).